Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-8472, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-8472-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN FOUR (4) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN EIGHT (8) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE $4 + 4 = 8$ WITH TERTIARY GLEASON PATTERN 3.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2.1 CM.
- C. THE CARCINOMA INVOLVES 15% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE POSTERIOR RIGHT BASE AND RIGHT MID REGIONS (SLIDES 3AA, 3BB, 3CC and 3DD).
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA BUT THERE IS TUMOR PRESENT IN THE SOFT TISSUE SURROUNDING THE SEMINAL VESICLES.
- G. TUMOR FOCALLY EXTENDS TO AN INKED SURGICAL MARGIN IN THE REGION OF POSTERIOR RIGHT MID (SLIDE 3BB).
- H. ALL OTHER EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- I. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- J. FOCAL ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- K. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- M. TNM HISTOLOGIC GRADE = G4.
- N. BENIGN PROSTATIC HYPERPLASIA.

PART 4: PROSTATE, APICAL MARGIN, BIOPSY -

- A. BENIGN FIBROMUSCULAR TISSUE.
- B. NEGATIVE FOR MALIGNANCY.

PART 5: PROSTATE, BLADDER NECK MARGIN, BIOPSY -

- A. BENIGN FIBROMUSCULAR TISSUE.
- B. NEGATIVE FOR MALIGNANCY.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	90%
WEIGHT OF PROSTATE:	47.94gm
TUMOR SIZE:	Maximum dimension: 21 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	Yes - Multifocal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	Focal tumor involvement at margin
LYMPH NODES EXAMINED:	12
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 737c36a8-bca1-4d53-9617-6393968c0d37 (TCGA-EJ-8472.D45B6FD0-5E0A-4A20-AB47-C8CC1FB32C86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).